Gene-level copy-number profile of tumor specimen TCGA-AA-A03J-01A from TCGA case TCGA-AA-A03J, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 65.7 years (23,986 days).
Specimen TCGA-AA-A03J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.38af736b-0669-4625-90f3-ce195e40b7d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A03J-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42dd5521-17e5-48b2-82f3-bea48987c087

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 9; copy number 2: 14,573; copy number 3: 23,342; copy number 4: 4,695; copy number 5: 16,217; copy number 12: 984.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A03J-01A-21D-A080-01): tumor purity 0.45, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 984 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:23,772,785–64,313,132, 984 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
